Gene-level copy-number profile of tumor specimen HCM-CSHL-0141-C18-01A from HCMI case HCM-CSHL-0141-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 67.2 years (24,563 days).
Specimen HCM-CSHL-0141-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d074f87-8bd5-410a-ac4a-41a28899a16d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0141-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/f79ce976-d59e-4dfd-892c-37de66dea324

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 955; copy number 2: 9,431; copy number 3: 28,895; copy number 4: 17,763; copy number 5: 1,251; copy number 6: 465; copy number 7: 17; copy number 9: 64; copy number 12: 21; copy number 15: 11; copy number 19: 26; copy number 20: 5; copy number 21: 2; copy number 36: 8.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,289,900–145,405,778, 1 gene: NBPF20.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 154 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:27,066,707–28,063,714, 20 genes, copy number 7–21 (within-gene range 6–21): C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1, KATNIP, AC002551.1, AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P.
- chr16:50,065,970–50,107,272, 1 gene, copy number 12 (within-gene range 5–12): HEATR3.
- chr16:50,098,264–52,677,747, 59 genes, copy number 12–36: RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7, MIR6771, BRD7, AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, SOD1P2, SALL1, AC009166.1, AC087564.1, AC009166.2, AC137494.1, AC137527.1, UNGP1, AC007344.1, HNRNPA1P48, RN7SKP142, LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1.
- chr17:21,428,263–21,574,517, 1 gene, copy number 7 (within-gene range 2–7): LINC02693.
- chr17:21,532,974–21,704,612, 9 genes, copy number 7: AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18.
- chr17:64,319,415–67,056,797, 64 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 442. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
